Gene-level copy-number profile of tumor specimen TCGA-DK-A3IT-01A from TCGA case TCGA-DK-A3IT, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 62.4 years (22,786 days).
Specimen TCGA-DK-A3IT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.d72f8527-d9f4-4514-bba8-bf905543d69c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A3IT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/80d8cf68-de94-4689-9755-4634502f68a9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 106; copy number 2: 12,914; copy number 3: 17,941; copy number 4: 22,719; copy number 5: 3,658; copy number 6: 1,526; copy number 7: 262; copy number 8: 264; copy number 9: 311; copy number 10: 86; copy number 11: 7; copy number 13: 25; copy number 14: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A3IT-01A-31D-A20B-01): tumor purity 0.46, ploidy 3.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 430 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:111,250,254–111,256,715, 1 gene, copy number 11: CHIAP1.
- chr2:185,738,804–185,833,290, 1 gene, copy number 14 (within-gene range 6–14): FSIP2.
- chr2:203,315,390–208,854,503, 111 genes, copy number 10–13 (within-gene range 2–13) (broad region; genes not listed).
- chr8:112,222,928–139,508,971, 311 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr21:39,525,583–39,802,096, 6 genes, copy number 11 (within-gene range 2–11): JCADP1, B3GALT5, B3GALT5-AS1, AF064860.1, AF064860.2, IGSF5.

Autosomal genes at a single copy (total copy number 1): 106. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
